Gene-level copy-number profile of tumor specimen ALCH-B3EJ-TTP1-A from ALCHEMIST case ALCH-B3EJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.8 years (25,868 days).
Specimen ALCH-B3EJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b2d52c53-d0f1-4a5e-a6a0-38d212ed62fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3EJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/663641ac-d8ec-4e40-8e77-b0f2b5d74789

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 553; copy number 1: 3,945; copy number 2: 52,781; copy number 3: 1,619; copy number 4: 20.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:160,453,428–160,700,632, 4 genes: LPAL2, LPA, AL109933.2, AL109933.1.
- chr6:165,117,195–165,117,524, 1 gene: AL136100.1.
- chr6:165,754,189–165,775,780, 2 genes (within-gene range 0–1): AL590302.2, AL590302.1.
- chr6:167,271,169–167,316,014, 1 gene: UNC93A.
- chr9:61,190,003–61,582,675, 8 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr12:111,304,142–111,451,623, 6 genes (within-gene range 0–2): MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3.
- chr17:67,019,934–67,056,797, 3 genes (within-gene range 0–2): AC005544.1, AC005544.2, CACNG1.
- chr18:37,234,119–37,762,131, 7 genes (within-gene range 0–1): AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:24,162,370–27,646,483, 3 genes: AC073534.1, ERVK-28, AC112702.1.
- chr20:3,659,248–3,767,781, 5 genes: GFRA4, ADAM33, SIGLEC1, HSPA12B, C20orf27.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,945. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
